Surgical pathology report (de-identified scan), TCGA case TCGA-50-7109, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-50-7109-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: LUNG, RIGHT LOWER LOBE, SUPERIOR SEGMENTECTOMY -

- A. MODERATELY DIFFERENTIATED ADENOCARCINOMA, 2.0 CM.
- B. BRONCHOVASCULAR MARGIN POSITIVE FOR ADENOCARCINOMA.
- C. FOCAL SUGGESTION OF ANGIOLYMPHATIC INVASION.
- D. STAPLED PARENCHYMAL MARGIN IS FREE OF CARCINOMA IN SLIDE SECTIONS.
- E. PERINEURAL INVASION IS PRESENT.
- F. EMPHYSEMATOUS CHANGE.
- G. AJCC PATHOLOGIC STAGE pT1 N0 MX.

PART 2: LYMPH NODE, LEVEL 4, BIOPSY -

ANTHRACOTIC LYMPH NODE, NO CARCINOMA IDENTIFIED (0/1).

PART 3: LYMPH NODE, LEVEL 10, BIOPSY -

SCANT FRAGMENT OF ANTHRACOTIC LYMPH NODE TISSUE, NO CARCINOMA IDENTIFIED.

PART 4: LYMPH NODE, LEVEL 7, BIOPSY -

FRAGMENTS OF ANTHRACOTIC LYMPH NODE TISSUE, NO CARCINOMA IDENTIFIED.

PART 5: LYMPH NODE, LEVEL 8, BIOPSY -

SCANT FRAGMENT OF ANTHRACOTIC LYMPH NODE TISSUE, NO CARCINOMA IDENTIFIED.

PART 6: LYMPH NODE, LEVEL 11 SUMP, BIOPSY -

FRAGMENT OF ANTHRACOTIC LYMPH NODE TISSUE, NO CARCINOMA IDENTIFIED.

COMMENT:

Immunohistochemical stain for TTF-1 is positive in the malignant cells, rare cells are p63 positive and carcinoma is negative for cytokeratin 5/6. These results support an adenocarcinoma. The carcinoma has acinar and solid patterns. Select slides of carcinoma who agree with the diagnosis.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY LUNG TUMORS

TUMOR LOCATION:	Right Lower Lobe
LUNG SEGMENT(S) INVOLVED:	Superior
PROCEDURE:	Segmental
TUMOR SIZE:	Maximum dimension: 2.0 cm
TUMOR TYPE:	Invasive adenocarcinoma
HISTOLOGIC GRADE:	G2, Moderately differentiated
EXTRAPULMONARY EXTENSION/INVASION OF TUMOR:	None identified
ANGIOLYMPHATIC INVASION:	Yes
TUMOR NECROSIS:	< or = to 50%
SURGICAL MARGIN INVOLVEMENT:	Yes
SURGICAL MARGIN SITE:	Bronchial margin, Vascular margin
INFLAMMATORY(DESMOPLASTIC) REACTION:	Moderate
N1 LYMPH NODES:	Number of N1 lymph nodes positive: 0 Number of N1 lymph nodes examined: 2
N2 LYMPH NODES:	Number of N2 lymph nodes positive: 0 Number of N2 lymph nodes examined: 3
T STAGE, PATHOLOGIC:	pT1a
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	Not applicable
ANCILLARY STUDIES:	Immunohistochemical stains

Source: NCI Genomic Data Commons file 6c47df55-1443-4c81-92bc-05fbbf4968f3 (TCGA-50-7109.A34C2391-F021-4B46-A4E9-8D9B7EE31402.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).